Gene-level copy-number profile of tumor specimen ALCH-ADU8-TTP1-A from ALCHEMIST case ALCH-ADU8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.2 years (20,910 days).
Specimen ALCH-ADU8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a76d0600-fd57-489e-9e80-9bf3503f51b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADU8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/84c41038-2430-4fdd-aa93-0378adac0dc1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 375; copy number 2: 57,821; copy number 3: 71; copy number 4: 23; copy number 7: 3; copy number 10: 3.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,019,329–2,030,758, 1 gene: GABRD.
- chr1:3,560,695–3,560,790, 1 gene (within-gene range 0–1): MIR551A.
- chr1:16,974,502–17,005,091, 3 genes (within-gene range 0–2): MFAP2, AL049569.2, AL049569.1.
- chr1:54,980,628–54,992,288, 2 genes: TMEM61, AL590440.1.
- chr2:131,491,160–131,491,236, 1 gene (within-gene range 0–2): MIR4784.
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr2:231,711,525–231,711,647, 1 gene (within-gene range 0–1): U4.
- chr4:1,793,293–1,856,156, 2 genes: FGFR3, LETM1.
- chr4:2,247,432–2,262,109, 2 genes: MXD4, MIR4800.
- chr7:128,830,406–128,859,274, 1 gene (within-gene range 0–2): FLNC.
- chr9:132,582,606–132,590,252, 1 gene: BARHL1.
- chr9:136,658,856–136,687,457, 3 genes (within-gene range 0–3): EGFL7, MIR126, AGPAT2.
- chr11:65,570,460–65,650,918, 7 genes (within-gene range 0–2): ZNRD2, FAM89B, EHBP1L1, KCNK7, MAP3K11, SIPA1, MIR4489.
- chr12:31,073,860–31,106,830, 3 genes (within-gene range 0–2): DDX11, SNORA75, AC008013.3.
- chr12:121,804,009–121,832,656, 1 gene: SETD1B.
- chr12:131,894,622–131,923,150, 2 genes: ULK1, AC131009.4.
- chr14:103,550,345–103,550,406, 1 gene: RNU7-160P.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr15:25,172,635–25,225,284, 29 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:41,825,099–41,894,053, 7 genes (within-gene range 0–2): AC020659.2, JMJD7, JMJD7-PLA2G4B, PLA2G4B, SPTBN5, RNA5SP393, MIR4310.
- chr16:424,243–424,543, 1 gene: AL023881.1.
- chr16:710,746–711,277, 1 gene (within-gene range 0–1): Z97653.1.
- chr16:784,974–800,737, 3 genes (within-gene range 0–2): RPUSD1, CHTF18, GNG13.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–2): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr17:2,384,073–2,401,104, 2 genes (within-gene range 0–2): MNT, AC006435.1.
- chr17:75,271,369–75,289,510, 2 genes: AC022211.2, SLC25A19.
- chr19:7,926,001–7,926,810, 1 gene (within-gene range 0–2): AC010336.5.
- chr19:19,645,198–19,663,676, 1 gene: ATP13A1.
- chr19:27,757,184–27,760,849, 1 gene (within-gene range 0–2): AC006504.1.
- chr19:45,506,579–45,526,983, 1 gene: VASP.
- chr20:17,613,678–17,682,295, 1 gene: RRBP1.
- chr21:43,805,758–43,812,567, 1 gene: AATBC.
- chr22:46,112,749–46,113,768, 3 genes (within-gene range 0–2): MIRLET7A3, MIR4763, MIRLET7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:143,716,340–143,722,458, 2 genes, copy number 7: MAPK15, AC105219.1.
- chr14:104,857,792–104,858,836, 1 gene, copy number 7: AL583810.1.
- chr22:20,338,805–20,354,387, 3 genes, copy number 10 (within-gene range 2–10): FAM230G, AC007731.2, AC007731.5.

Autosomal genes at a single copy (total copy number 1): 375. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
